TARGET case TARGET-10-PARFLV — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9527e028-131c-584b-99f7-3a782159f495

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 16 years; Vital status: Dead; Days to death: 334 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 16.2 years (5,906 days); Year of diagnosis: 2007; Days to last follow up: 334 days.
   Treatment given: Protocol identifier: AALL0232.

Follow-up (3 entries)
- Days to follow up: 293 days; Days to first event: 293 days; First event: Relapse.
- Days to follow up: 334 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Nervous system, NOS; Year of follow up: 2008.
- Days to follow up: 334 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Bone marrow.

Molecular and laboratory tests (laboratory values grouped by visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- BCR–ABL1 fusion: Negative.
- ETV6–RUNX1 fusion (FISH): Negative.
- KMT2A rearrangement (FISH): Negative.
- Trisomy 10: Negative.
- Trisomy 4: Negative.
- Day 0: Leukocytes 215 ×10³/µL.
- Day 8: Bone Marrow blast count 48%; Minimal Residual Disease (Flow Cytometry) 2.4%.
- Day 15: Bone Marrow blast count 10%.
- Day 29: Bone Marrow blast count 1%; Minimal Residual Disease (Flow Cytometry) 0.57%.
- Minimal Residual Disease (Flow Cytometry) 0%.

Biospecimens (3 samples)
- Sample TARGET-10-PARFLV-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARFLV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-10-PARFLV-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 334
- WBC at Diagnosis: 214.5
- CNS Status at Diagnosis: CNS 1
- Testicular Involvement: No
- MRD Day 8: 2.4
- MRD Day 8 Sensitivity: 0.01
- MRD Day 29: 0.57
- MRD Day 29 Sensitivity: 0.01
- MRD End Consolidation: 0
- MRD End Consolidation Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: Yes
- Testes Site of Relapse: No
- Other Site of Relapse: No
- ETV6 RUNX1 Fusion Status: Negative
- TRISOMY 4 10 Status: Negative
- MLL Status: Negative
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 48
- BMA Blasts Day 15: 10
- BMA Blasts Day 29: 1
- Down Syndrome: No
- DNA Index: 1.08
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
